Somatic mutation profile of tumor specimen ALCH-ABN3-TTP1-A (aliquot ALCH-ABN3-TTP1-A-1-0-D-A488-36) from ALCHEMIST case ALCH-ABN3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.9 years (22,239 days).
Specimen ALCH-ABN3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc207d6e-e397-4c4b-800b-4eda81c9a379.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABN3-NB1-A (Blood Derived Normal), aliquot ALCH-ABN3-NB1-A-1-0-D-A488-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43ffa56d-1513-4873-b04a-34e41c5f3a26

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.2252A>G p.Y751C | Missense Mutation (SNP) | VAF 54/445 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1227802601; called by muse, mutect2, varscan2
- DHX16 | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866178679; called by muse, mutect2
- KCNN2 | c.136G>T p.A46S (on ENST00000264773; = p.A258S on NM_021614.4) | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV53290576; called by muse, mutect2
- MAGEB10 | c.803C>G p.P268R | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63311651; called by muse, mutect2, varscan2
- PID1 | c.155A>C p.K52T (on ENST00000354069 / NM_001330156.1; = p.K50T on NM_017933.5) | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs745434084; called by muse, mutect2, varscan2
- AP1G2 | c.697T>G p.S233A | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ARID4A | c.3536A>G p.N1179S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.97); called by muse, mutect2
- BIRC7 | c.851T>G p.I284S (on ENST00000217169 / NM_139317.3; = p.I266S on NM_022161.4) | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CAMK2B | c.1171A>C p.I391L | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.089); called by muse, mutect2
- NPAT | c.3947G>A p.C1316Y | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PHRF1 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF150 | c.757A>G p.K253E | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- NUAK2 | c.129C>T p.H43= | Silent (SNP) | VAF 28/275 reads (10%) | called by muse, mutect2
- PDLIM5 | c.1548T>C p.V516= | Silent (SNP) | VAF 21/230 reads (9%) | called by muse, mutect2
- SSC5D | c.3729G>T p.T1243= | Silent (SNP) | VAF 22/160 reads (14%) | called by muse, varscan2
- MEF2C | c.810+28T>C | Intron (SNP) | VAF 12/268 reads (4%) | catalogued as rs1451298571; called by muse, mutect2
- VAMP3 | c.-82C>T | 5'UTR (SNP) | VAF 22/209 reads (11%) | called by muse, mutect2
